Somatic mutation profile of tumor specimen TCGA-D7-6524-01A (aliquot TCGA-D7-6524-01A-11D-1800-08) from TCGA case TCGA-D7-6524, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.5 years (19,532 days).
Specimen TCGA-D7-6524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88315ddc-0645-4925-9c60-a829f9bdb9cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6524-10A (Blood Derived Normal), aliquot TCGA-D7-6524-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a7854e4-347b-460c-a37c-a69a8c7f60f9

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Nonsense Mutation 6, Intron 2, Splice Site 2, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as COSV61016031; called by muse, mutect2, varscan2
- ADAMTS9 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201212787, COSV55777752; called by muse, mutect2
- ANK2 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232729014, COSV52151937; called by muse, mutect2, varscan2
- ARID1A | c.6762C>A p.Y2254* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV61373199, COSV61374456; called by muse, mutect2, varscan2
- ARSL | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66965029; called by muse, mutect2, varscan2
- ATP13A3 | c.1880C>A p.P627Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV55462848, COSV55463927; called by muse, mutect2, varscan2
- BRWD1 | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as rs1404541031, COSV60894136; called by muse, mutect2, varscan2
- CABP2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV53708576; called by muse, mutect2
- CCDC42 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs143164438; called by muse, mutect2, varscan2
- CDH2 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs568089577, COSV52273145, COSV52275674; called by muse, mutect2, varscan2
- CILP2 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383709843, COSV52273596; called by muse, mutect2, varscan2
- CMTR1 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs1007372135, COSV65089916, COSV99056384; called by muse, mutect2, varscan2
- CPT1A | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.653); catalogued as rs1229097082, COSV55754249; called by muse, mutect2
- CTNNB1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV62695239; called by muse, mutect2, varscan2
- CTNNB1 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs758551763, COSV62695247; called by muse, mutect2, varscan2
- CYLD | c.2744A>G p.Y915C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61093724; called by muse, mutect2
- DLGAP2 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1259369243, COSV70096369; called by muse, mutect2
- DMGDH | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54862166; called by muse, mutect2, varscan2
- EPHA8 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.73); catalogued as COSV51265392; called by mutect2, varscan2
- ESR2 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV50829475; called by muse, mutect2, varscan2
- FAM136A | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV50682498; called by muse, mutect2, varscan2
- FAM90A1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.957); catalogued as rs755387831, COSV56711174; called by muse, mutect2, varscan2
- FAT1 | c.13136A>G p.N4379S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs770597395, COSV71673162; called by muse, mutect2, varscan2
- FBXL13 | c.2140T>A p.S714T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.013); catalogued as COSV57536399; called by muse, mutect2, varscan2
- FMR1NB | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63272730; called by muse, mutect2, varscan2
- GOLGA3 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151069773; called by muse, mutect2, varscan2
- GREB1 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1033548852; called by muse, mutect2
- HNRNPR | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as rs887758919, COSV56420763; called by muse, mutect2, varscan2
- KRT73 | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV99988929; called by mutect2, varscan2
- LTBP2 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375244685; called by muse, mutect2, varscan2
- MYO1H | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755229590, COSV60442476, COSV60444565; called by muse, mutect2, varscan2
- NEGR1 | c.825T>G p.N275K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV60838015; called by muse, mutect2, varscan2
- NIN | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1467525890, COSV55384973, COSV55402819; called by muse, mutect2
- NKX3-1 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769852677, COSV66511867; called by muse, mutect2, varscan2
- NTHL1 | c.360C>G p.D120E (on ENST00000219066; = p.D112E on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs1186300844, COSV54592644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR13F1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs1408260796, COSV58251226; called by muse, mutect2, varscan2
- OR4C13 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as rs1555015845, COSV73648692; called by muse, mutect2, varscan2
- PCDH15 | c.4573A>T p.K1525* (on ENST00000617271 / NM_001142770.3; = p.K1513I on NM_001142769.3) | Nonsense Mutation (SNP) | VAF 28/296 reads (9%) | catalogued as COSV64683839; called by muse, mutect2
- PDGFRB | c.2744A>G p.N915S | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.268); catalogued as rs754345719, COSV55803031; called by muse, mutect2
- PIPOX | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV60141311; called by muse, mutect2, varscan2
- PKN2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV60130702; called by muse, mutect2, varscan2
- POLR3B | c.3137G>A p.R1046H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57277495; called by muse, mutect2, varscan2
- PTPRA | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as COSV53779948; called by muse, mutect2
- PXDN | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs565398993, COSV53230056; called by muse, mutect2, varscan2
- REV3L | c.7817A>G p.Y2606C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747486955, COSV62617272; called by muse, mutect2, varscan2
- ROBO2 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.14); catalogued as COSV59903912; called by muse, mutect2, varscan2
- RPS6KA2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs779109340, COSV55818300; called by muse, mutect2, varscan2
- SLITRK1 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV65674910; called by muse, mutect2, varscan2
- SLITRK6 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68389771; called by muse, mutect2, varscan2
- SOX30 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53936664; called by muse, mutect2, varscan2
- SPTA1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs201519091, COSV63750201, COSV63750984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN5 | c.5164C>T p.R1722W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs373585698; called by mutect2, varscan2
- SYNE1 | c.11745C>A p.F3915L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54942339; called by muse, mutect2, varscan2
- SYT16 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760675924, COSV70855812; called by muse, mutect2, varscan2
- TAF7L | c.835+1G>A p.X279_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV61256598; called by muse, mutect2, varscan2
- TERF2 | c.575T>A p.V192D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99651726; called by muse, mutect2, varscan2
- TGFBR1 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV66625248; called by muse, mutect2, varscan2
- USP40 | c.2108T>A p.I703N | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV52478877; called by muse, mutect2, varscan2
- ZNF510 | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as rs377426198, COSV56296758; called by muse, mutect2, varscan2
- DMD | c.956_960+3del p.X319_splice | Splice Site (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- POLR2A | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN1A | c.5396C>T p.P1799L (on ENST00000303395 / NM_001202435.3; = p.P1788L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEDC2 | c.145del p.A49Lfs*2 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by pindel, varscan2
- ANKRD34A | c.1002C>T p.S334= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV60160558; called by muse, mutect2, varscan2
- ASGR1 | c.780C>T p.D260= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs761828049, COSV52648600; called by muse, mutect2, varscan2
- BRINP2 | c.144C>T p.S48= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs746624639, COSV64176563; called by muse, mutect2, varscan2
- ERICH3 | c.3798C>T p.V1266= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV58598599; called by muse, mutect2, varscan2
- FCGBP | c.9411C>T p.V3137= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- FEV | c.354T>C p.H118= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1409876459, COSV55386365; called by muse, mutect2
- GUK1 | c.30C>T p.S10= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs140072078; called by muse, mutect2, varscan2
- KCNG4 | c.387C>T p.A129= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1362710513, COSV100377019, COSV57583210; called by muse, mutect2
- ORAI3 | c.579G>T p.V193= | Silent (SNP) | VAF 41/369 reads (11%) | catalogued as rs1195870112, COSV52685152; called by muse, mutect2, varscan2
- PLA2G15 | c.1179C>T p.I393= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs777321800, COSV54718294; called by muse, mutect2, varscan2
- PPP3CB | c.1212C>A p.I404= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV61151451; called by muse, mutect2, varscan2
- RPS6KA1 | c.1809G>T p.L603= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV65175775; called by muse, mutect2, varscan2
- STAC | c.735C>T p.G245= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs747482136, COSV56208595; called by muse, mutect2
- SYNE1 | c.8403C>T p.Y2801= (on ENST00000367255 / NM_182961.4; = p.Y2808= on NM_033071.3) | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs757104773, COSV54898013; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- TECTA | c.4338G>A p.T1446= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV50696498; called by muse, mutect2, varscan2
- TERF2 | c.576C>T p.V192= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs761040166, COSV99651724; called by muse, mutect2, varscan2
- TRIM3 | c.663C>T p.S221= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV61983458; called by muse, mutect2, varscan2
- TRPS1 | c.2439G>T p.L813= (on ENST00000220888 / NM_001330599.2; = p.L826= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as COSV55232520, COSV99628808; called by muse, mutect2, varscan2
- UQCRH | c.276A>G p.*92= | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as COSV61176138; called by muse, mutect2
- ZIC5 | c.1272G>A p.P424= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs774077826, COSV57437173; called by muse, mutect2
- ZNF581 | c.270C>T p.P90= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs556294832, COSV54401552, COSV54402161; called by muse, mutect2, varscan2
- ZNF700 | c.381C>T p.D127= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs371245717, COSV54311568; called by muse, mutect2, varscan2
- FOLH1B | n.1796T>A | RNA (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10424G>A | Intron (SNP) | VAF 14/94 reads (15%) | catalogued as COSV57113885; called by muse, mutect2, varscan2
- P4HA1 | c.*2A>C | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99697280; called by muse, mutect2
- TTN | c.10360+4807G>T | Intron (SNP) | VAF 15/127 reads (12%) | catalogued as COSV59962129; called by muse, mutect2, varscan2
